Gene-level copy-number profile of tumor specimen TCGA-ZF-AA5H-01A from TCGA case TCGA-ZF-AA5H, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 60.6 years (22,122 days).
Specimen TCGA-ZF-AA5H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.39544ef6-f640-46a0-a3d3-e6f827b2f237.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-AA5H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/03a82e5a-2c54-4981-9677-a57c206545a4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,783; copy number 2: 27,060; copy number 3: 17,593; copy number 4: 4,981; copy number 5: 5,561; copy number 6: 1,223; copy number 7: 773; copy number 8: 386; copy number 9: 134; copy number 10: 70; copy number 11: 18; copy number 12: 45; copy number 14: 30; copy number 17: 59; copy number 21: 26; copy number 22: 7; copy number 28: 62; copy number 29: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-AA5H-01A-11D-A390-01): tumor purity 0.58, ploidy 2.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:33,969,567–34,009,595, 2 genes: AF279873.1, AF279873.4.
- chr8:75,407,914–75,566,834, 1 gene (within-gene range 0–2): HNF4G.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,400 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–190,801,658, 1,375 genes, copy number 5 (broad region; genes not listed).
- chr3:69,999,550–71,754,229, 13 genes, copy number 5 (within-gene range 3–5): SAMMSON, AC139700.1, UQCRHP4, MDFIC2, AC104633.1, AC104633.2, COX6CP6, HMGB1P36, RNU6-281P, FOXP1, AC097634.4, FOXP1-AS1, MIR1284.
- chr3:72,691,705–74,521,140, 27 genes, copy number 5 (within-gene range 3–5): RNA5SP136, AC097369.4, SHQ1, AC134050.1, PSMD12P1, LAPTM4BP2, GXYLT2, Metazoa_SRP, FTH1P23, PPP4R2, RNU7-19P, EBLN2, RNU6-557P, RNU2-64P, CCDC75P1, RNU6-1270P, PDZRN3, RNU7-119P, PDZRN3-AS1, AC117489.1, AC108725.1, LINC02005, Metazoa_SRP, LINC02047, AC016930.1, AKR1B1P2, CNTN3.
- chr3:78,597,239–79,767,998, 1 gene, copy number 5 (within-gene range 3–8): ROBO1.
- chr3:78,938,009–80,677,898, 8 genes, copy number 5–8: RN7SL751P, AC117461.1, MIR3923, HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1.
- chr3:164,001,606–198,222,513, 638 genes, copy number 5–6 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6–7 (broad region; genes not listed).
- chr5:56,975,593–58,859,394, 23 genes, copy number 5 (within-gene range 2–5): AC114973.1, AC034244.1, AC034244.2, Y_RNA, GPBP1, AC025470.1, AC025470.2, SALL4P1, ACTBL2, LINCR-0003, AC008780.1, AC106822.1, LINC02225, LINC02101, AC008786.1, PGAM1P1, PLK2, GAPT, AC008814.1, MIR548AE2, LINC02108, RAB3C, AC016642.1.
- chr7:36,389,821–63,636,617, 476 genes, copy number 5–22 (broad region; genes not listed).
- chr7:110,108,031–136,437,785, 407 genes, copy number 5–29 (within-gene range 2–29) (broad region; genes not listed).
- chr7:138,298,088–138,703,062, 10 genes, copy number 5: AC008155.1, PTMAP10, IMPDH1P3, TRIM24, RPS3AP28, SVOPL, AC013429.2, AC013429.1, AC020983.1, UQCRFS1P2.
- chr7:142,618,849–145,681,369, 131 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr7:154,943,687–155,003,124, 1 gene, copy number 5 (within-gene range 2–5): PAXIP1.
- chr7:155,003,448–157,417,439, 51 genes, copy number 5: PAXIP1-AS1, HTR5A-AS1, HTR5A, AC093726.3, AC092628.2, AC092628.1, RN7SKP280, AC099552.1, AC099552.3, AC099552.5, AC099552.4, AC099552.2, AC144652.1, INSIG1, BLACE, AC008060.1, AC008060.4, AC008060.5, AC008060.3, EN2, CNPY1, AC009403.2, AC008060.2, AC009403.3, AC009403.1, RBM33, SHH, AC021218.1, Y_RNA, AC093813.1, LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6.
- chr7:158,730,995–159,233,377, 7 genes, copy number 5 (within-gene range 3–5): ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:40,519,565–49,076,093, 147 genes, copy number 5 (broad region; genes not listed).
- chr8:84,162,118–145,066,685, 969 genes, copy number 5 (broad region; genes not listed).
- chr9:23,291,544–23,682,662, 5 genes, copy number 6: AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2.
- chr9:26,746,953–28,670,286, 29 genes, copy number 5 (within-gene range 3–5): AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1.
- chr9:31,644,576–37,358,149, 213 genes, copy number 5 (broad region; genes not listed).
- chr9:81,583,683–82,780,194, 16 genes, copy number 5 (within-gene range 3–5): TLE1, AL591368.1, RNU6-1035P, RNA5SP287, AL158154.1, SPATA31D5P, AL158154.2, SPATA31D4, AL158154.3, SPATA31D3, SPATA31D2P, AL162726.3, SPATA31D1, SPATA31B1P, DDX10P2, AL158047.1.
- chr11:79,402,022–79,402,109, 1 gene, copy number 5: MIR708.
- chr11:80,321,620–80,762,826, 4 genes, copy number 6: AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720.
- chr11:101,129,077–103,479,863, 54 genes, copy number 5: PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr13:65,787,932–114,337,626, 590 genes, copy number 5 (broad region; genes not listed).
- chr14:58,284,773–81,743,749, 511 genes, copy number 5 (broad region; genes not listed).
- chr16:59,855,353–68,835,541, 197 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr16:68,885,576–68,885,677, 1 gene, copy number 5: Y_RNA.
- chr16:71,563,430–80,167,577, 195 genes, copy number 5–10 (broad region; genes not listed).
- chr16:80,179,129–80,180,682, 1 gene, copy number 5: AC022166.2.
- chr18:47,390–48,410,752, 752 genes, copy number 6–8 (within-gene range 2–8) (broad region; genes not listed).
- chr18:64,872,264–66,604,138, 10 genes, copy number 6: AC090348.1, AC007948.1, AC007631.1, LINC01916, AC090358.1, CDH7, AC023394.2, AC023394.1, PRPF19P1, CDH19.
- chr20:87,250–35,280,043, 727 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr22:18,833,694–20,495,844, 100 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,783. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
